Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PE-01A from TCGA case TCGA-VQ-A8PE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 78.7 years (28,755 days).
Specimen TCGA-VQ-A8PE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.62eff908-e1cd-436f-89d7-ac4354b0e268.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a3adbbe1-51c8-47a4-aa9e-7238256f90d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,787; copy number 2: 28,415; copy number 3: 19,307; copy number 4: 4,801; copy number 5: 1,723; copy number 6: 750; copy number 7: 19; copy number 9: 4; copy number 16: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PE-01A-11D-A40Z-01): tumor purity 0.5, ploidy 2.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,498 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,210,570–10,796,650, 18 genes, copy number 5 (within-gene range 3–5): KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1.
- chr3:93,843,764–96,814,407, 27 genes, copy number 6: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr4:137,807,706–142,847,432, 75 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:148,445,703–149,024,624, 1 gene, copy number 9 (within-gene range 4–16): AC002460.2.
- chr4:148,693,032–149,062,522, 5 genes, copy number 9–16: AC108935.1, ATP5MGP4, AC002460.1, RNU7-197P, AC108156.1.
- chr6:31,739,677–32,445,046, 65 genes, copy number 5 (broad region; genes not listed).
- chr8:13,536,029–13,705,506, 5 genes, copy number 7: RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2.
- chr8:17,801,345–17,910,365, 5 genes, copy number 6: AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2.
- chr8:38,996,754–40,172,612, 22 genes, copy number 5: ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:74,320,613–75,034,558, 15 genes, copy number 5 (within-gene range 3–5): GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1.
- chr8:75,167,704–75,176,656, 1 gene, copy number 5: LINC02886.
- chr8:78,805,293–78,956,082, 1 gene, copy number 6 (within-gene range 4–6): AC083837.1.
- chr8:79,259,402–88,887,573, 154 genes, copy number 5–6 (broad region; genes not listed).
- chr8:100,337,595–104,589,024, 108 genes, copy number 5 (broad region; genes not listed).
- chr8:106,697,427–110,809,894, 44 genes, copy number 5: TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3.
- chr8:110,933,263–110,934,533, 1 gene, copy number 5: MTCO1P47.
- chr8:115,408,496–122,127,184, 66 genes, copy number 5–7 (broad region; genes not listed).
- chr10:32,009,015–32,232,245, 8 genes, copy number 6: KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13.
- chr11:46,116,578–46,386,608, 11 genes, copy number 6: AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr11:46,428,653–46,451,889, 3 genes, copy number 6: AC024293.1, MIR3160-1, MIR3160-2.
- chr13:84,520,103–86,462,734, 16 genes, copy number 5: MTND4P1, MTND5P3, LINC00333, AL445588.1, AL356313.1, LINC00375, AL160154.1, LINC00351, AL356413.1, SLITRK6, AL162373.1, MOB1AP1, AL354994.1, FO624990.1, DDX6P2, AL445207.1.
- chr13:87,219,004–110,307,157, 289 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:33,924,227–34,462,774, 1 gene, copy number 5 (within-gene range 3–5): EGLN3.
- chr14:34,416,687–34,630,160, 11 genes, copy number 5 (within-gene range 3–5): AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3.
- chr14:77,474,394–77,769,742, 10 genes, copy number 5: ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178.
- chr14:77,821,030–77,821,142, 1 gene, copy number 5: Y_RNA.
- chr16:88,234,785–88,537,031, 5 genes, copy number 6 (within-gene range 2–6): AC138512.1, ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr17:47,694,081–48,430,275, 32 genes, copy number 5 (within-gene range 3–5): TBKBP1, TBX21, OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6, PNPO, AC018521.1, AC018521.2, PRR15L, CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2, CBX1, RNU6-1201P, SNX11, SKAP1, MIR1203, SKAP1-AS1, RNU6-1152P.
- chr18:3,025,069–3,219,968, 4 genes, copy number 7 (within-gene range 4–7): AP005431.1, SNORA70, MYOM1, RNU7-25P.
- chr19:27,902,595–34,964,229, 167 genes, copy number 6 (broad region; genes not listed).
- chr19:36,916,329–38,636,955, 68 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:87,250–16,053,197, 290 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:15,552,157–34,269,344, 391 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:34,245,953–34,246,537, 1 gene, copy number 5: AL035458.1.
- chr20:41,402,083–41,618,384, 1 gene, copy number 6 (within-gene range 4–6): CHD6.
- chr20:41,485,571–64,313,132, 576 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,977. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
